Gene-level copy-number profile of tumor specimen C3N-00297-01 (profiled together with C3N-00297-02, C3N-00297-03) from CPTAC case C3N-00297, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.1 years (25,254 days).
Specimen C3N-00297-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43a1ea26-6853-4b8b-83e2-ecfb635b45bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00297-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/c6f257a0-8ebe-4523-8129-6b4c476a60ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 12,038; copy number 2: 41,296; copy number 3: 4,842; copy number 4: 187; copy number 5: 25; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:26,015,669–26,016,369, 1 gene: RPEP2.
- chr3:30,606,601–30,699,576, 3 genes (within-gene range 0–1): TGFBR2, AC096921.1, AC096921.2.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:102,347,211–103,479,863, 27 genes, copy number 5–8 (within-gene range 1–8): BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.

Autosomal genes at a single copy (total copy number 1): 9,695. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
